Gene-level copy-number profile of tumor specimen TCGA-AR-A250-01A from TCGA case TCGA-AR-A250, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.3 years (21,309 days).
Specimen TCGA-AR-A250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.66b51ec8-15d1-4d1e-9edf-28f2a6b037d9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A250-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/710f71ad-75a7-4606-adba-7010d8811fbe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 10,522; copy number 2: 21,646; copy number 3: 23,840; copy number 4: 2,604; copy number 5: 334; copy number 6: 111; copy number 7: 227; copy number 10: 151; copy number 11: 8; copy number 12: 56; copy number 13: 32; copy number 14: 1; copy number 15: 14; copy number 16: 60; copy number 20: 43; copy number 22: 35; copy number 25: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A250-01A-31D-A166-01): tumor purity 0.53, ploidy 4.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–1): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes (within-gene range 0–1): AL031432.2, RHD, SDHDP6.
- chr8:18,989,279–19,000,952, 1 gene (within-gene range 0–1): AC009884.1.
- chr8:40,519,565–41,032,998, 4 genes: AC010857.1, ZMAT4, AC048387.1, RNU6-356P.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 669 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:72,280,969–76,421,868, 87 genes, copy number 7–10 (broad region; genes not listed).
- chr13:18,467,172–24,613,983, 166 genes, copy number 7–10 (broad region; genes not listed).
- chr13:25,863,250–26,905,861, 20 genes, copy number 7: AL157366.1, RN7SL741P, RNY1P3, SHISA2, LINC00415, ATP8A2P3, PRUNEP1, RNF6, AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1.
- chr13:29,864,372–30,429,758, 19 genes, copy number 10–11: Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, AL161893.1, LINC01058, UBE2L5.
- chr13:30,466,117–30,482,312, 1 gene, copy number 10: AL353648.1.
- chr17:39,461,486–40,304,657, 39 genes, copy number 7–15 (within-gene range 5–15): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6.
- chr17:40,317,698–40,318,676, 1 gene, copy number 7: AC080112.4.
- chr17:48,690,481–52,535,701, 144 genes, copy number 11–25 (broad region; genes not listed).
- chr17:58,556,678–61,392,838, 95 genes, copy number 16–22 (within-gene range 1–22) (broad region; genes not listed).
- chr17:61,452,404–63,611,184, 64 genes, copy number 7 (broad region; genes not listed).
- chr17:63,636,601–63,637,113, 1 gene, copy number 7: EEF1DP7.
- chr17:66,197,693–67,697,261, 32 genes, copy number 13 (within-gene range 3–13): PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1.

Autosomal genes at a single copy (total copy number 1): 8,101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
